Somatic mutation profile of tumor specimen TARGET-10-PAPEFH-04A (aliquot TARGET-10-PAPEFH-04A-01D) from TARGET case TARGET-10-PAPEFH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,543 days).
Specimen TARGET-10-PAPEFH-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67f87b46-84ed-4f93-bcde-9ef0a6ca2cf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPEFH-14A (Bone Marrow Normal), aliquot TARGET-10-PAPEFH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d437ef6-0efb-401d-932d-4875d4b91a8a

The open-access MAF lists 36 somatic variants for this specimen: 20 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 15, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2624C>A p.T875N | Missense Mutation (SNP) | VAF 338/369 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1057520016, COSV67598981; ClinVar: likely pathogenic; called by mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 31/40 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 46/52 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC15 | c.2281G>A p.V761M | Missense Mutation (SNP) | VAF 88/622 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs371494047; called by mutect2, varscan2
- CSF1R | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 254/587 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs200702302; called by muse, mutect2, varscan2
- DGAT2L6 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 172/390 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60717471; called by muse, mutect2, varscan2
- DNAJC5G | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs539866520, COSV56079741, COSV56080959; called by muse, mutect2, varscan2
- DNMT1 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV61578022; called by muse, mutect2
- FIGN | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60765322; called by muse, mutect2, varscan2
- HMCN1 | c.6812C>T p.A2271V | Missense Mutation (SNP) | VAF 188/446 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs747638841, COSV54890259; called by muse, mutect2, varscan2
- HSPB7 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV58890380, COSV58891124, COSV58894389; called by muse, mutect2, varscan2
- KMT2D | c.857_858insGGAC p.K287Dfs*2 | Frame Shift Ins (INS) | VAF 79/201 reads (39%) | catalogued as COSV56464530, COSV99982352; called by mutect2, pindel, varscan2
- MUC5B | c.9344C>T p.T3115M | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs563537111, COSV71591530; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 123/251 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2A | c.4063G>A p.V1355I | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs746137888; called by muse, mutect2, varscan2
- QRICH2 | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53152302; called by muse, mutect2, varscan2
- RIPK3 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs767757637, COSV53474776; called by muse, mutect2, varscan2
- SPRY3 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as COSV57142461; called by muse, mutect2
- UBR4 | c.12349T>C p.S4117P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64386371; called by muse, mutect2, varscan2
- USP13 | c.1089G>C p.A363= | Splice Region (SNP) | VAF 278/634 reads (44%) | catalogued as COSV55864320, COSV55871274; called by muse, mutect2, varscan2
- ABCA7 | c.2436G>C p.L812= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV54027259, COSV54032669; called by muse, mutect2
- AKAP13 | c.7878G>T p.V2626= (on ENST00000394518 / NM_007200.5; = p.V2630= on NM_006738.6) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV63453072; called by muse, mutect2, varscan2
- BAG6 | c.1881C>T p.P627= (on ENST00000676571; = p.P580= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs759687609; called by muse, mutect2, varscan2
- CCDC160 | c.153C>T p.S51= | Silent (SNP) | VAF 65/181 reads (36%) | catalogued as rs774192405, COSV66251451; called by muse, mutect2, varscan2
- EXD1 | c.1185A>G p.L395= | Silent (SNP) | VAF 146/356 reads (41%) | catalogued as rs750237755, COSV59253408; called by muse, mutect2
- GJB3 | c.768C>A p.G256= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV64904496; called by muse, mutect2, varscan2
- HSPG2 | c.1005A>G p.G335= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- KDM3B | c.852C>G p.G284= | Silent (SNP) | VAF 96/208 reads (46%) | catalogued as COSV58689704; called by muse, mutect2, varscan2
- MFSD2A | c.450C>T p.P150= (on ENST00000372809 / NM_001136493.3; = p.P137= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 80/175 reads (46%) | catalogued as rs749348699, COSV65685354; called by muse, mutect2, varscan2
- PTPN13 | c.795T>G p.R265= | Silent (SNP) | VAF 91/186 reads (49%) | catalogued as rs746374562, COSV57405158; called by muse, mutect2, varscan2
- PTPRS | c.3369C>T p.N1123= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs747415864, COSV53614526; called by muse, mutect2
- SLC12A2 | c.684G>A p.R228= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs1369727363, COSV52470157; called by muse, mutect2, varscan2
- TMC1 | c.2178G>A p.A726= | Silent (SNP) | VAF 19/329 reads (6%) | catalogued as rs555517698, COSV52772402; ClinVar: likely benign; called by muse, mutect2
- VPS13B | c.1194G>A p.T398= | Silent (SNP) | VAF 103/560 reads (18%) | catalogued as COSV62017990; called by muse, varscan2
- ZFP1 | c.957G>A p.T319= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as rs775977714, COSV100181960; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-15199A>T | Intron (SNP) | VAF 197/418 reads (47%) | catalogued as COSV67442502; called by muse, mutect2, varscan2
